TCGA case TCGA-DG-A2KM — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Ontario Institute for Cancer Research. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e87fadbe-c58c-41d1-b413-8cf6ce70ce94

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 46.0 years (16,808 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N1; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Lymph nodes positive: 4; Lymph nodes tested: 9; Lymphatic invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 118 days; Days to treatment end: 155 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 118 days; Days to treatment end: 160 days; Treatment dose: 5,500 cGy; Number of fractions: 30; Treatment anatomic sites: Regional Site.

Follow-up (9 entries)
- Days to follow up: 1,218 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,946 days (5.3 years); Disease response: Tumor Free.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease; Timepoint: Preoperative.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement; Timepoint: Preoperative.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement; Timepoint: Preoperative.
- ECOG performance status: 0; Timepoint: Other.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement; Timepoint: Preoperative.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement; Timepoint: Preoperative.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement; Timepoint: Preoperative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Height: 169 cm.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DG-A2KM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 170 mg.
  Slide TCGA-DG-A2KM-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
- Sample TCGA-DG-A2KM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DG-A2KM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 2; Total pregnancy count: 2; Tobacco smoking history indicator: 1; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion: Absent; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation therapy xrt type: External beam radiation; Radiation therapy dose paraaortic nodes: 4500.
- Follow-up form 1, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 2.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,946 days; disease-specific survival: no event (censored), 1,946 days; disease-free interval: no event (censored), 1,946 days; progression-free interval: no event (censored), 1,946 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DG-A2KM-01A-11D-A17U-01): tumor purity 0.17, ploidy 1.96, whole-genome doublings 0.
